Somatic mutation profile of tumor specimen TCGA-F5-6814-01A (aliquot TCGA-F5-6814-01A-31D-1924-10) from TCGA case TCGA-F5-6814, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.0 years (20,828 days).
Specimen TCGA-F5-6814-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 423a643b-1795-4d6b-9f3b-46396ff2a6d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6814-10A (Blood Derived Normal), aliquot TCGA-F5-6814-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18118987-2447-4e6a-9516-69be8f87d03f

The open-access MAF lists 10,717 somatic variants for this specimen: 8,079 protein-altering or splice-affecting, 1,623 silent, 1,015 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,884, Silent 1,623, Nonsense Mutation 988, 3'UTR 466, Intron 288, RNA 98, Splice Site 97, 5'UTR 93, Splice Region 85, 3'Flank 39, 5'Flank 30, Frame Shift Ins 11.

Variants (750 of 10,717; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6445C>T p.R2149* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs61750654, CM990078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.6118C>T p.R2040* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as rs61753038, CM032170, COSV64674774; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ALK | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | hotspot (GDC flag); catalogued as rs865931787, COSV66559513; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASNS | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs373645939; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9454C>T p.R3152* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as rs587783292, CM142031, COSV54124029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by mutect2, varscan2
- BMPR1A | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 55/128 reads (43%) | catalogued as rs587782400, CM014516, COSV64404910; ClinVar: pathogenic; called by muse, varscan2
- BRCA1 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 44/150 reads (29%) | catalogued as rs730881473, CM128922, COSV58783876, COSV58789484; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.8009C>T p.S2670L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359035, CD1414729, CM043983, CM065037, COSV66453386; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDK12 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71000029; called by muse, mutect2, varscan2
- CLTC | c.4237G>T p.E1413* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs1567971126; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by mutect2, varscan2
- DICER1 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as rs886037684, CM161670, COSV58617147; ClinVar: pathogenic; called by muse, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- DMD | c.10108C>T p.R3370* | Nonsense Mutation (SNP) | VAF 44/61 reads (72%) | catalogued as rs104894787, CM084898, CS921169, COSV58909013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.5530C>T p.R1844* | Nonsense Mutation (SNP) | VAF 75/107 reads (70%) | catalogued as rs1064325, CM040024, COSV63753245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by mutect2, varscan2
- DYNC1H1 | c.9092C>T p.T3031M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs879253956, COSV64136723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERRFI1 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 48/123 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV66310643; called by muse, mutect2, varscan2
- FBN1 | c.6751T>C p.C2251R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs112836174, CM022788, CM995303, COSV57315985; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN2 | c.1610A>G p.D537G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs565227443, COSV99330282; ClinVar: likely pathogenic; called by mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGF8 | c.352C>T p.R118* (on ENST00000344255 / NM_033164.4; = p.R100* on NM_006119.6) | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs876661330, CM104201, COSV60142801; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IFIH1 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376048533, CM150829; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2C | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1403418496, COSV51343575; called by muse, mutect2
- MAT1A | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs913435613; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MECOM | c.2542C>T p.R848* (on ENST00000468789 / NM_001105078.4; = p.R1036* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as rs1560118923, COSV52968817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED13 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs773685207, COSV67263402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTRR | c.1442C>T p.S481L (on ENST00000264668; = p.S454L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853062, CM032288, COSV52942686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.5044C>T p.R1682* | Nonsense Mutation (SNP) | VAF 112/224 reads (50%) | catalogued as rs797045769, COSV56944290; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as rs1057516414, CM141333, COSV62635208; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs281865444, CM101144, CM1514930, COSV61016269; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 30/40 reads (75%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, varscan2
- PNPT1 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772153760, COSV53177224; ClinVar: likely pathogenic; called by muse, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 67/214 reads (31%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 60/168 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, varscan2
- RDH11 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as rs606231424, CM149678, COSV67282577; ClinVar: pathogenic; called by muse, varscan2
- RRM2B | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as rs121918310, CM094862, COSV52566674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by mutect2, varscan2
- RUNX1 | c.877C>T p.R293* (on ENST00000344691 / NM_001001890.3; = p.R320* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as rs1569008655, CM086912, COSV55867803; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2177-1G>T p.X726_splice (on ENST00000303395 / NM_001202435.3; = p.X715_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as rs763400390, COSV57669256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDR9C7 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs530109812, COSV53288823; ClinVar: pathogenic; called by mutect2, varscan2
- SIN3A | c.3310C>T p.R1104* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs879255621, COSV64581642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC6A3 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs431905516, CM108192, COSV54364068; ClinVar: pathogenic; called by mutect2, varscan2
- SLC9A6 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 53/69 reads (77%) | catalogued as rs122461162, CM081439, COSV65787941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908511, CM992676, COSV59512800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 41/52 reads (79%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.88858C>T p.R29620* (on ENST00000591111; = p.R22196* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 32/375 reads (9%) | catalogued as rs1553528016, COSV59881459; ClinVar: likely pathogenic; called by muse, mutect2
- A2M | c.4186G>A p.V1396M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59386217; called by muse, mutect2, varscan2
- A2M | c.1444C>A p.L482M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100588949; called by muse, varscan2
- A2ML1 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV55290369; called by muse, mutect2, varscan2
- A2ML1 | c.720T>G p.I240M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs1565467131, COSV55290395; called by muse, varscan2
- AADACL2 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as rs778055819, COSV62930334, COSV62931292; called by muse, mutect2, varscan2
- AADACL4 | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs1343817270, COSV66106224; called by muse, varscan2
- AASDH | c.2152A>C p.N718H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV52706442; called by muse, mutect2, varscan2
- AASS | c.1977G>T p.M659I | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV62789912; called by muse, mutect2, varscan2
- AASS | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV62789917; called by muse, varscan2
- AASS | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 49/162 reads (30%) | catalogued as COSV62789544; called by muse, mutect2, varscan2
- AASS | c.1566G>T p.K522N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs1197452495, COSV62789922; called by muse, mutect2, varscan2
- AASS | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431496936, COSV62789773; called by muse, mutect2, varscan2
- AATK | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as rs201194092, COSV58687865; called by muse, mutect2, varscan2
- ABCA1 | c.6694G>T p.D2232Y | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV66066089; called by muse, mutect2, varscan2
- ABCA1 | c.6505A>C p.K2169Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV66066094; called by muse, mutect2, varscan2
- ABCA1 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66066100; called by mutect2, varscan2
- ABCA10 | c.2531A>C p.K844T | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52221800; called by muse, mutect2, varscan2
- ABCA10 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV52221811; called by muse, varscan2
- ABCA10 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52221828; called by muse, mutect2, varscan2
- ABCA12 | c.7536C>A p.Y2512* (on ENST00000272895 / NM_173076.3; = p.Y2194* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as CM1413676, COSV55958425, COSV55960192; called by muse, mutect2, varscan2
- ABCA12 | c.5132A>C p.K1711T (on ENST00000272895 / NM_173076.3; = p.K1393T on NM_015657.3) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV55958447; called by muse, mutect2, varscan2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, varscan2
- ABCA12 | c.1858G>T p.E620* (on ENST00000272895 / NM_173076.3; = p.E302* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV55958497; called by muse, mutect2, varscan2
- ABCA12 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as rs758756716, COSV55958514; called by muse, mutect2, varscan2
- ABCA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762065937, CM130513, COSV55948982; called by muse, mutect2, varscan2
- ABCA13 | c.1983G>C p.E661D | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs749643186, COSV70026121, COSV70028213; called by muse, varscan2
- ABCA13 | c.4393G>T p.D1465Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV70028245; called by muse, mutect2, varscan2
- ABCA13 | c.5956A>G p.I1986V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs757708070; called by muse, mutect2
- ABCA13 | c.7841T>C p.I2614T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV71287406; called by muse, mutect2, varscan2
- ABCA13 | c.10594G>A p.E3532K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759818169, COSV71284774; called by muse, mutect2, varscan2
- ABCA4 | c.2796G>T p.K932N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs775951957, COSV64673378; called by muse, mutect2, varscan2
- ABCA4 | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV64673389; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2, varscan2
- ABCA5 | c.3587A>C p.K1196T | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV67016723; called by muse, mutect2, varscan2
- ABCA5 | c.3405A>C p.E1135D | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV67016730; called by muse, mutect2, varscan2
- ABCA5 | c.2264A>C p.K755T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.194); catalogued as COSV67016735; called by muse, mutect2, varscan2
- ABCA5 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | catalogued as COSV67016738; called by muse, mutect2, varscan2
- ABCA6 | c.3640C>A p.L1214I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV52638374; called by muse, mutect2, varscan2
- ABCA6 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs138416476, COSV52637314; called by muse, varscan2
- ABCA7 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs149293300; called by muse, varscan2
- ABCA8 | c.3692C>A p.S1231Y | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV52200664, COSV52214378; called by muse, mutect2, varscan2
- ABCA8 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272259090; called by muse, varscan2
- ABCA8 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV52200713; called by muse, mutect2, varscan2
- ABCA9 | c.850T>G p.L284V | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as COSV60624475; called by muse, mutect2
- ABCB1 | c.1976G>T p.R659I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV55950601; called by muse, mutect2, varscan2
- ABCB1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV55950447, COSV55950615; called by muse, mutect2, varscan2
- ABCB1 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as COSV55944621, COSV55950626; called by muse, mutect2, varscan2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 29/85 reads (34%) | catalogued as rs1222604496, COSV55945529; called by muse, varscan2
- ABCB11 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV55585060; called by mutect2, varscan2
- ABCB4 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as COSV55934998; called by muse, mutect2, varscan2
- ABCB4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1269792276, COSV55941342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51709101; called by muse, mutect2, varscan2
- ABCB5 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51709108, COSV51714330; called by muse, mutect2, varscan2
- ABCB6 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs776541657; called by mutect2, varscan2
- ABCC12 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); catalogued as rs751380328, COSV60917978; called by muse, mutect2, varscan2
- ABCC2 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV64970875; called by muse, mutect2, varscan2
- ABCC2 | c.4121G>A p.R1374Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773345306, COSV64986065; called by muse, mutect2, varscan2
- ABCC3 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV53321344; called by muse, mutect2, varscan2
- ABCC4 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as rs1400854469, COSV65312418; called by muse, mutect2, varscan2
- ABCC8 | c.2408A>C p.E803A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV56850129; called by muse, mutect2, varscan2
- ABCC9 | c.4394G>A p.R1465H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867034453, COSV53970654; called by muse, mutect2, varscan2
- ABCC9 | c.3119G>T p.S1040I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV53970673; called by muse, mutect2, varscan2
- ABCD1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs1315933477, COSV54384585; called by mutect2, varscan2
- ABCD2 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58051682; called by muse, mutect2, varscan2
- ABCF2 | c.1198A>G p.N400D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV55182860; called by muse, mutect2, varscan2
- ABCG2 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV52945802; called by mutect2, varscan2
- ABCG2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs780975480, COSV52945734; called by muse, mutect2, varscan2
- ABCG4 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV56642446; called by muse, mutect2, varscan2
- ABCG4 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1228303791, COSV56643499; called by muse, mutect2, varscan2
- ABCG8 | c.1832G>T p.R611I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV55393098, COSV55396475; called by muse, mutect2, varscan2
- ABHD1 | c.273G>A p.Q91= | Splice Region (SNP) | VAF 17/70 reads (24%) | catalogued as COSV53205974, COSV53207729, COSV99574889; called by muse, mutect2, varscan2
- ABHD2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs772771831, COSV61773895; called by muse, mutect2, varscan2
- ABHD2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373748122; called by mutect2, varscan2
- ABHD5 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50006535, COSV50007131; called by muse, mutect2, varscan2
- ABHD6 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV55910618; called by muse, mutect2, varscan2
- ABI2 | c.1061A>C p.N354T (on ENST00000295851 / NM_001375719.1; = p.N287T on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.239); catalogued as COSV53691768; called by muse, mutect2, varscan2
- ABL2 | c.605G>A p.S202N (on ENST00000502732 / NM_007314.4; = p.S187N on NM_005158.5) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1184140649, COSV61013781; called by muse, mutect2, varscan2
- ABLIM1 | c.1689G>T p.K563N | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV53305776; called by muse, mutect2, varscan2
- ABLIM1 | c.1114A>G p.I372V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1428428259; called by muse, mutect2, varscan2
- ABRAXAS1 | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as COSV100426755, COSV58949811; called by muse, mutect2, varscan2
- AC004922.1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 30/144 reads (21%) | catalogued as COSV53556768; called by muse, mutect2, varscan2
- AC006059.2 | c.1064C>A p.A355D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV59606701, COSV59606806; called by muse, mutect2
- AC006059.2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182436192, COSV59606181; called by mutect2, varscan2
- AC013477.1 | c.2624C>A p.S875Y | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53653743; called by muse, mutect2, varscan2
- AC098582.1 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52020012; called by muse, mutect2, varscan2
- AC127029.3 | c.692A>C p.D231A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as CM972824; called by muse, mutect2, varscan2
- ACACB | c.4821C>T p.I1607= | Splice Region (SNP) | VAF 14/37 reads (38%) | catalogued as rs776234149, COSV58128696; called by muse, mutect2, varscan2
- ACAD10 | c.2138T>G p.L713R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58156490; called by muse, mutect2, varscan2
- ACADM | c.1261A>C p.N421H | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63720341; called by muse, mutect2, varscan2
- ACAP1 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50135766; called by muse, mutect2, varscan2
- ACAP2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV58751797; called by muse, mutect2, varscan2
- ACBD3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as rs781141478, COSV64730313; called by muse, mutect2, varscan2
- ACBD3 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV64730341; called by muse, mutect2, varscan2
- ACBD6 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777457819, COSV62571410, COSV62574403; called by muse, varscan2
- ACCS | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV99772961; called by mutect2, varscan2
- ACE2 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as rs773848804, COSV53024902; called by muse, mutect2, varscan2
- ACIN1 | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs551895203, COSV52975944; called by muse, mutect2, varscan2
- ACIN1 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs779416155, COSV52975961; called by mutect2, varscan2
- ACKR3 | c.400T>G p.F134V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56021592; called by muse, mutect2, varscan2
- ACKR4 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 34/229 reads (15%) | catalogued as rs1239393842, COSV51442494; called by muse, mutect2, varscan2
- ACLY | c.965C>A p.T322N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61250604; called by muse, mutect2, varscan2
- ACOX3 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV62712744; called by muse, mutect2, varscan2
- ACOXL | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1485364025; called by muse, mutect2, varscan2
- ACOXL | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs749080854; called by muse, mutect2, varscan2
- ACRV1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.056); catalogued as COSV59754897; called by muse, mutect2, varscan2
- ACSBG2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as rs751060741, COSV53123875; called by muse, mutect2, varscan2
- ACSF2 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV55951521; called by muse, mutect2, varscan2
- ACSF3 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs929495492; called by muse, mutect2, varscan2
- ACSF3 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV58078316; called by muse, mutect2, varscan2
- ACSL4 | c.331A>C p.N111H (on ENST00000340800 / NM_022977.2; = p.N70H on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61614282; called by muse, varscan2
- ACSM2A | c.253G>T p.E85* (on ENST00000219054; = p.E6* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | catalogued as COSV54590263, COSV99525659; called by muse, mutect2, varscan2
- ACSM2B | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV61657788; called by muse, mutect2, varscan2
- ACSM4 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68069400; called by muse, mutect2, varscan2
- ACSS3 | c.1198A>T p.I400F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54090636; called by muse, mutect2, varscan2
- ACSS3 | c.2013A>C p.E671D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV54090647; called by muse, mutect2
- ACTB | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV59318368; called by muse, mutect2, varscan2
- ACTL7A | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs555458305, COSV61776457; called by mutect2, varscan2
- ACTN1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51991475, COSV51998345; called by muse, mutect2, varscan2
- ACTR3 | c.1080A>G p.P360= | Splice Region (SNP) | VAF 28/74 reads (38%) | catalogued as COSV54300892; called by muse, mutect2, varscan2
- ACTR5 | c.804T>G p.Y268* | Nonsense Mutation (SNP) | VAF 47/106 reads (44%) | catalogued as COSV54760656; called by muse, mutect2, varscan2
- ACTR8 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.151); catalogued as rs766624409, COSV51635599; called by muse, mutect2, varscan2
- ACTRT2 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs772980431; called by muse, mutect2, varscan2
- ACVR1C | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV54645986, COSV54649361; called by muse, mutect2, varscan2
- ACVR2A | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54022005, COSV54025026; called by muse, mutect2, varscan2
- ACVR2A | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs770920471, COSV54021831; called by muse, mutect2, varscan2
- ACVR2A | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV54022026; called by muse, mutect2, varscan2
- ADAM20 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV56455081; called by muse, mutect2, varscan2
- ADAM21 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs149756061, COSV50792703; called by muse, mutect2, varscan2
- ADAM21 | c.666T>G p.I222M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV50792732; called by muse, mutect2, varscan2
- ADAM22 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV55976098, COSV55976380; called by muse, mutect2, varscan2
- ADAM28 | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV56098004; called by muse, mutect2, varscan2
- ADAM28 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56100312, COSV99738185; called by muse, mutect2, varscan2
- ADAM28 | c.723T>G p.L241= | Splice Region (SNP) | VAF 31/73 reads (42%) | catalogued as COSV56100332; called by muse, mutect2, varscan2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, varscan2
- ADAM30 | c.1892T>C p.F631S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV65561041; called by muse, mutect2, varscan2
- ADAM32 | c.253A>C p.N85H | Missense Mutation (SNP) | VAF 28/483 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as COSV101165492; called by muse, mutect2
- ADAM32 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV65949046; called by muse, varscan2
- ADAMTS12 | c.3631C>T p.P1211S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV61262413; called by muse, mutect2, varscan2
- ADAMTS12 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371132100, COSV61261873; called by muse, varscan2
- ADAMTS14 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as rs757459157, COSV64601838; called by muse, mutect2, varscan2
- ADAMTS16 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV56991979; called by muse, varscan2
- ADAMTS18 | c.2274G>T p.Q758H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV51408458; called by muse, mutect2, varscan2
- ADAMTS20 | c.1973G>A p.C658Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67131103, COSV67134545; called by muse, varscan2
- ADAMTS20 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.964); catalogued as rs747342811, COSV67131114; called by muse, mutect2, varscan2
- ADAMTS3 | c.2607A>C p.K869N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54390926; called by muse, mutect2, varscan2
- ADAMTS5 | c.2548T>G p.F850V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV53178854; called by muse, mutect2, varscan2
- ADAMTS7 | c.3222G>T p.E1074D | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV66307118; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs201573079, COSV65891957; called by muse, varscan2
- ADAMTSL1 | c.3682C>A p.L1228I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV65892067; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4220T>C p.V1407A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as COSV101000529; called by mutect2, varscan2
- ADARB1 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62344135; called by muse, mutect2, varscan2
- ADARB2 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV67222499; called by muse, mutect2, varscan2
- ADCK1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs140603078; called by muse, mutect2, varscan2
- ADCY10 | c.4345C>A p.L1449I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749690491, COSV63239583, COSV63240944, COSV63245296; called by mutect2, varscan2
- ADCY10 | c.3109T>G p.F1037V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV63240633; called by muse, mutect2
- ADCY2 | c.2469G>T p.Q823H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV57871147; called by muse, mutect2, varscan2
- ADCY2 | c.3093G>A p.M1031I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57871164; called by muse, varscan2
- ADCY3 | c.2572C>T p.R858C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761536857, COSV53167372, COSV99567603; called by muse, mutect2, varscan2
- ADCY5 | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs150642009; called by muse, mutect2, varscan2
- ADCY6 | c.3356G>A p.S1119N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57167682; called by muse, mutect2, varscan2
- ADCY8 | c.2924C>A p.S975Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV53906532; called by muse, mutect2, varscan2
- ADCY8 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753611079, COSV53906544, COSV53932051; called by muse, mutect2, varscan2
- ADCY8 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs780241069, COSV53906557, COSV99651887; called by muse, varscan2
- ADCY9 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.048); catalogued as rs374081146; called by muse, mutect2, varscan2
- ADCYAP1 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as rs373051517, COSV52486281; called by muse, mutect2, varscan2
- ADGRA3 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs758572665, COSV51561845; called by muse, mutect2, varscan2
- ADGRB3 | c.537A>C p.L179F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65393996; called by muse, mutect2, varscan2
- ADGRB3 | c.1737T>G p.I579M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV65394002; called by muse, mutect2, varscan2
- ADGRE1 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1446134676, COSV51675257; called by muse, mutect2, varscan2
- ADGRE2 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV59693391; called by muse, mutect2, varscan2
- ADGRE5 | c.1273G>A p.E425K (on ENST00000242786 / NM_078481.4; = p.E332K on NM_001784.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs772157605, COSV54410429; called by muse, mutect2, varscan2
- ADGRF1 | c.2445G>T p.Q815H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51945401; called by mutect2, varscan2
- ADGRG2 | c.2965G>A p.E989K (on ENST00000379869 / NM_001079858.3; = p.E986K on NM_005756.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs1481978044; called by mutect2, varscan2
- ADGRG2 | c.1923T>G p.I641M (on ENST00000379869 / NM_001079858.3; = p.I638M on NM_005756.4) | Missense Mutation (SNP) | VAF 106/127 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61338972; called by muse, mutect2, varscan2
- ADGRG4 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV54955452; called by muse, varscan2
- ADGRG4 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs377239456, COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRL2 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54665888; called by muse, mutect2, varscan2
- ADGRL2 | c.2863G>A p.V955I (on ENST00000370717 / NM_001366005.1; = p.V942I on NM_012302.4) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs756113269, COSV54665919; called by muse, mutect2, varscan2
- ADGRL3 | c.3395+1G>T p.X1132_splice (on ENST00000506720 / NM_001322402.2; = p.X1064_splice on NM_015236.6) | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as COSV72230500; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, varscan2
- ADGRL3 | c.4107G>T p.K1369N (on ENST00000506720 / NM_001322402.2; = p.K1258N on NM_015236.6) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV72230501; called by muse, mutect2, varscan2
- ADGRL4 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV66060841; called by muse, mutect2
- ADGRL4 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs762428327, COSV66061481; called by muse, varscan2
- ADGRV1 | c.9989G>T p.R3330I | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV67984740, COSV67989632; called by muse, mutect2, varscan2
- ADGRV1 | c.13049C>A p.S4350Y | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as COSV67984745; called by muse, mutect2, varscan2
- ADGRV1 | c.14511G>T p.K4837N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV104434983; called by mutect2, varscan2
- ADH1C | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs748223863, COSV72463413; called by mutect2, varscan2
- ADH5 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV56448097; called by muse, mutect2, varscan2
- ADIPOQ | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as COSV57859060; called by muse, mutect2, varscan2
- ADPRS | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1275608083, COSV52880945; called by muse, mutect2, varscan2
- ADRB3 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.086); catalogued as COSV61461949; called by muse, mutect2, varscan2
- ADSS1 | c.792C>T p.F264= | Splice Region (SNP) | VAF 6/16 reads (38%) | catalogued as rs530966674, COSV58274688; called by muse, mutect2, varscan2
- AFAP1L1 | c.1984T>G p.L662V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV99696100; called by mutect2, varscan2
- AFDN | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs770737214, COSV60044055; called by muse, mutect2, varscan2
- AFF2 | c.232T>G p.Y78D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60664275; called by muse, mutect2, varscan2
- AFF2 | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs782144498, COSV53988390; called by muse, mutect2, varscan2
- AFF4 | c.3154G>T p.G1052W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54794530; called by muse, mutect2, varscan2
- AFG3L2 | c.2214G>T p.K738N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52314337; called by muse, mutect2, varscan2
- AFG3L2 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52314343; called by muse, mutect2, varscan2
- AFM | c.1481C>A p.A494D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV56918833, COSV99888469; called by muse, mutect2, varscan2
- AGA | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as rs776196445, COSV52806234; called by mutect2, varscan2
- AGAP1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58325321; called by muse, mutect2, varscan2
- AGBL1 | c.2076-1G>T p.X692_splice | Splice Site (SNP) | VAF 71/90 reads (79%) | catalogued as COSV101224141; called by muse, varscan2
- AGBL2 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100102052; called by muse, mutect2, varscan2
- AGBL3 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV51951928; called by muse, mutect2, varscan2
- AGBL5 | c.1907T>C p.L636S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV59936499; called by muse, mutect2, varscan2
- AGK | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV62594431; called by muse, mutect2, varscan2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV64617106; called by muse, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGTPBP1 | c.3062G>A p.R1021Q (on ENST00000357081 / NM_001330701.2; = p.R981Q on NM_015239.2) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.982); catalogued as rs1212529549, COSV61274268; called by muse, mutect2, varscan2
- AGTR1 | c.232T>G p.L78V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.203); catalogued as COSV62558053; called by muse, mutect2, varscan2
- AGTR1 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV62558064; called by muse, varscan2
- AGTR1 | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV62558070; called by muse, varscan2
- AGTR2 | c.358T>A p.F120I | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV64156447; called by muse, varscan2
- AGXT2 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV51486186; called by muse, mutect2, varscan2
- AHCTF1 | c.6221C>T p.S2074L (on ENST00000366508; = p.S2048L on NM_015446.5) | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1259917481, COSV58249600; called by muse, mutect2, varscan2
- AHCYL1 | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV63208642; called by muse, mutect2, varscan2
- AHCYL1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63208649; called by muse, mutect2, varscan2
- AHI1 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55627433; called by muse, mutect2, varscan2
- AHNAK | c.6977T>C p.I2326T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV57212717; called by muse, mutect2, varscan2
- AHNAK | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as rs763485398, COSV57217512; called by mutect2, varscan2
- AHNAK2 | c.17347G>A p.D5783N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as rs562319458, COSV60914814; called by muse, mutect2, varscan2
- AHNAK2 | c.13521G>T p.K4507N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60914825; called by muse, mutect2, varscan2
- AHR | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV54123390; called by muse, mutect2, varscan2
- AIFM1 | c.749A>C p.Q250P | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1181577633, COSV54854464; called by muse, mutect2, varscan2
- AIM2 | c.841T>G p.L281V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.554); catalogued as COSV63699605; called by muse, mutect2, varscan2
- AIM2 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.35); catalogued as COSV63699607; called by muse, mutect2, varscan2
- AK5 | c.485C>A p.S162Y (on ENST00000354567 / NM_174858.3; = p.S136Y on NM_012093.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222950271, COSV100481494; called by muse, mutect2, varscan2
- AK7 | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV50871307; called by muse, mutect2, varscan2
- AK8 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53754090; called by muse, mutect2, varscan2
- AK8 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.369); catalogued as rs750120409, COSV53754113; called by mutect2, varscan2
- AK8 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV53752896; called by muse, mutect2, varscan2
- AK9 | c.4178T>G p.F1393C | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69848871; called by muse, mutect2, varscan2
- AK9 | c.3578C>T p.T1193M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs372289484; called by muse, mutect2, varscan2
- AK9 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.176); catalogued as COSV53421163; called by muse, mutect2, varscan2
- AKAP12 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as rs775211883, COSV53574645; called by muse, mutect2, varscan2
- AKAP12 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs199808949; called by muse, mutect2, varscan2
- AKAP12 | c.4226A>C p.K1409T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV53574656; called by muse, mutect2, varscan2
- AKAP17A | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs1381124929, COSV100002352, COSV58309519; called by muse, mutect2, varscan2
- AKAP17A | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs749621675, COSV100002481; called by muse, mutect2, varscan2
- AKAP4 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.952); catalogued as COSV62074373; called by muse, mutect2, varscan2
- AKAP6 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs748087074, COSV55213194; called by muse, mutect2, varscan2
- AKAP6 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55213214; called by muse, varscan2
- AKAP6 | c.3661G>T p.E1221* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV55213226; called by muse, mutect2, varscan2
- AKAP6 | c.4892G>T p.R1631I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55210150; called by muse, varscan2
- AKAP6 | c.5161C>T p.R1721C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs758563777, COSV55209326; called by mutect2, varscan2
- AKAP9 | c.3715G>T p.D1239Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs758832151, COSV62345360; called by muse, mutect2, varscan2
- AKR1C3 | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs1804059, COSV65910407, COSV65910448; called by muse, mutect2, varscan2
- AKR1D1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs148732404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT3 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV55615749, COSV55620508; called by muse, mutect2
- AKTIP | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs771776966, COSV50877307; called by muse, mutect2, varscan2
- AL136295.1 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55303127, COSV99841751; called by muse, mutect2, varscan2
- ALAS1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV59627828; called by muse, mutect2, varscan2
- ALAS2 | c.1392G>T p.R464S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV58190289; called by muse, mutect2, varscan2
- ALB | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55737962, COSV55739723; called by muse, varscan2
- ALDH16A1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs534259783; called by mutect2, varscan2
- ALDH1A2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51079346; called by muse, varscan2
- ALDH1A2 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51078962, COSV51080994; called by muse, varscan2
- ALDH1A2 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51081030, COSV99990611; called by muse, varscan2
- ALDH1L2 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99310956; called by muse, mutect2, varscan2
- ALDH1L2 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.608); catalogued as COSV51555701; called by muse, mutect2
- ALDH6A1 | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV63246311; called by muse, mutect2, varscan2
- ALG14 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV64634812; called by muse, mutect2, varscan2
- ALG6 | c.988-2A>C p.X330_splice | Splice Site (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99673446; called by mutect2, varscan2
- ALG9 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as COSV67644331; called by muse, varscan2
- ALG9 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782123768, COSV67644339; called by muse, varscan2
- ALK | c.2579G>T p.R860I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1194282326, COSV66567323, COSV66575044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.954C>T p.G318= | Splice Region (SNP) | VAF 21/48 reads (44%) | catalogued as rs1045878688; called by muse, mutect2, varscan2
- ALKAL1 | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62130317; called by muse, mutect2, varscan2
- ALKBH8 | c.507A>C p.K169N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV52834152, COSV52835172; called by muse, mutect2, varscan2
- ALLC | c.34-1G>T p.X12_splice | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV52994480, COSV99377368; called by muse, mutect2, varscan2
- ALMS1 | c.3557G>A p.R1186K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV52509357; called by muse, mutect2, varscan2
- ALMS1 | c.4725G>T p.E1575D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV52509367; called by muse, mutect2, varscan2
- ALMS1 | c.6836T>G p.F2279C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52509378; called by muse, mutect2, varscan2
- ALMS1 | c.9392C>A p.S3131Y | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52509393; called by muse, mutect2, varscan2
- ALMS1 | c.11147T>G p.F3716C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV52509403; called by muse, mutect2, varscan2
- ALOX5 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs143978950; called by muse, mutect2, varscan2
- ALOX5 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs754256319, COSV65550760; called by muse, mutect2, varscan2
- ALOXE3 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 58/81 reads (72%) | catalogued as COSV59074205; called by muse, mutect2, varscan2
- ALOXE3 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV59075341; called by muse, mutect2, varscan2
- ALPK1 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs774768880; called by muse, mutect2, varscan2
- ALPK2 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs766605419, COSV64491438; called by mutect2, varscan2
- ALX1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV57492068; called by muse, varscan2
- ALX1 | c.290A>C p.D97A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV57492180; called by muse, varscan2
- AMBP | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV54323432; called by muse, mutect2, varscan2
- AMD1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370327573, COSV64387377; called by muse, mutect2, varscan2
- AMDHD2 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1386454513, COSV53550668; called by muse, mutect2, varscan2
- AMER1 | c.1386A>C p.E462D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs1282807993, COSV57659171; called by mutect2, varscan2
- AMER3 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774553121, COSV58468223; called by mutect2, varscan2
- AMIGO1 | c.-65-1G>T | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100881105; called by muse, mutect2, varscan2
- AMIGO2 | c.370T>G p.L124V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56974178; called by muse, mutect2
- AMMECR1L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55760188, COSV99761263; called by muse, mutect2, varscan2
- AMN | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs979571435, COSV54486069; called by muse, mutect2, varscan2
- AMN1 | c.130A>C p.M44L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55671317; called by muse, mutect2, varscan2
- AMOT | c.2184G>T p.Q728H (on ENST00000371959 / NM_001113490.1; = p.Q319H on NM_133265.3) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59063158; called by muse, mutect2, varscan2
- AMPD1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1344319121, COSV62416032; called by muse, varscan2
- AMPD1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs149424604, COSV100814939; called by muse, mutect2, varscan2
- AMPD1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs369335745, COSV100815133, COSV62416441; called by mutect2, varscan2
- AMPD3 | c.2188C>T p.R730* (on ENST00000396553 / NM_001025389.2; = p.R739* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs755071594, COSV67330872; called by muse, mutect2, varscan2
- AMY2A | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 102/291 reads (35%) | catalogued as COSV70214481, COSV70214523; called by muse, mutect2, varscan2
- AMY2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs750768619, COSV70215035; called by muse, mutect2, varscan2
- AMY2A | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 32/246 reads (13%) | catalogued as COSV101340620, COSV70214212; called by mutect2, varscan2
- ANAPC4 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs1354497748, COSV59543994; called by muse, mutect2, varscan2
- ANAPC4 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs535292691, COSV59544001; called by muse, mutect2, varscan2
- ANAPC4 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59544011; called by muse, mutect2, varscan2
- ANGPTL1 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99328343; called by muse, mutect2
- ANK1 | c.3291G>T p.E1097D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1264919212, COSV55880917; called by mutect2, varscan2
- ANK2 | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV52145522; called by muse, mutect2, varscan2
- ANK2 | c.4937C>T p.T1646I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV52147786; called by muse, mutect2, varscan2
- ANK2 | c.5971C>T p.R1991W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442984107, COSV52148543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.8216C>A p.S2739Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52160018; called by muse, mutect2, varscan2
- ANK2 | c.8882C>A p.S2961Y | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV52160031, COSV52162552; called by muse, mutect2, varscan2
- ANK2 | c.10431C>A p.F3477L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV52160041; called by muse, mutect2, varscan2
- ANK3 | c.12395C>A p.S4132Y (on ENST00000280772 / NM_001320874.2; = p.S653Y on NM_001149.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55056815; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as rs1424318695; called by muse, mutect2, varscan2
- ANKMY1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142461924; called by muse, mutect2, varscan2
- ANKRD12 | c.5320A>G p.T1774A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV50824490; called by muse, mutect2, varscan2
- ANKRD17 | c.7163C>A p.S2388Y | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV58219693; called by muse, varscan2
- ANKRD17 | c.4825A>C p.S1609R | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV58219702; called by muse, mutect2, varscan2
- ANKRD18A | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs758919038, COSV57632842; called by muse, mutect2, varscan2
- ANKRD18A | c.1306A>C p.I436L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV68802784; called by muse, mutect2, varscan2
- ANKRD18B | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 52/131 reads (40%) | catalogued as COSV52086652, COSV52087926; called by muse, mutect2, varscan2
- ANKRD18B | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV52087936; called by muse, mutect2, varscan2
- ANKRD18B | c.2498C>A p.S833* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV52087950, COSV52088238; called by muse, mutect2, varscan2
- ANKRD26 | c.4594G>T p.D1532Y | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV101063362; called by muse, mutect2
- ANKRD26 | c.3169G>T p.D1057Y | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs969387790, COSV65773914; called by muse, mutect2, varscan2
- ANKRD30A | c.1802C>A p.S601Y (on ENST00000611781; = p.S545Y on NM_052997.2) | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV64609660; called by muse, mutect2, varscan2
- ANKRD30A | c.2666C>A p.S889Y (on ENST00000611781; = p.S833Y on NM_052997.2) | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV100653521, COSV64609685; called by muse, mutect2, varscan2
- ANKRD30BL | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54612027; called by muse, mutect2, varscan2
- ANKRD34B | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV58613539; called by muse, mutect2, varscan2
- ANKRD34C | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1289243854; called by muse, mutect2, varscan2
- ANKRD35 | c.2115G>A p.W705* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV62910188; called by muse, mutect2, varscan2
- ANKRD35 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1193647861; called by muse, mutect2, varscan2
- ANKRD42 | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); catalogued as COSV52615725; called by muse, mutect2, varscan2
- ANKRD44 | c.2317T>G p.Y773D | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56554616; called by muse, mutect2, varscan2
- ANKRD50 | c.1838C>A p.T613K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72385513; called by muse, mutect2, varscan2
- ANKRD50 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV72385516; called by muse, mutect2, varscan2
- ANKRD50 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs368512857; called by mutect2, varscan2
- ANKRD52 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as COSV57284203; called by muse, mutect2, varscan2
- ANKS1B | c.3347T>G p.F1116C (on ENST00000547776 / NM_152788.4; = p.F282C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228773; called by muse, mutect2, varscan2
- ANKS1B | c.2355A>C p.K785N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV61349966; called by muse, mutect2, varscan2
- ANKS1B | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV61349979; called by muse, mutect2, varscan2
- ANKS6 | c.2603G>A p.S868N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV62050180; called by muse, mutect2, varscan2
- ANKZF1 | c.478T>C p.F160L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.034); catalogued as COSV55476455; called by muse, mutect2, varscan2
- ANLN | c.2688G>T p.K896N | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56076102; called by muse, mutect2, varscan2
- ANO1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1253195741; called by mutect2, varscan2
- ANO10 | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV52730987; called by muse, mutect2, varscan2
- ANO3 | c.1433T>G p.F478C | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV55554244; called by muse, varscan2
- ANO3 | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV56790495, COSV56807883; called by muse, mutect2, varscan2
- ANO4 | c.2230G>T p.E744* (on ENST00000392977 / NM_001286615.2; = p.E709* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100152393; called by muse, mutect2, varscan2
- ANO5 | c.1593C>A p.F531L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.253); catalogued as COSV61087878; called by muse, mutect2, varscan2
- ANO5 | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs886042760, COSV61081922; ClinVar: uncertain significance; called by muse, varscan2
- ANP32B | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV59586594; called by muse, varscan2
- ANP32E | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs782603651, COSV58481542; called by muse, mutect2, varscan2
- ANTXR1 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58013256; called by muse, mutect2, varscan2
- ANTXR2 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55018477; called by muse, mutect2, varscan2
- ANXA1 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57411196; called by muse, mutect2, varscan2
- ANXA1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57411031; called by muse, mutect2, varscan2
- ANXA10 | c.98T>G p.F33C | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV63738951; called by muse, mutect2, varscan2
- ANXA13 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as COSV51622300; called by muse, mutect2, varscan2
- ANXA6 | c.1794G>T p.K598N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62906675; called by mutect2, varscan2
- ANXA6 | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV100637082; called by muse, mutect2, varscan2
- AOX1 | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV65981470; called by muse, mutect2, varscan2
- AP3M2 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs1437840697, COSV51528511; called by muse, mutect2, varscan2
- AP4E1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs151135245; ClinVar: uncertain significance; called by muse, mutect2
- AP4E1 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs754437475, COSV55916257; called by muse, mutect2, varscan2
- AP5M1 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55105265; called by muse, mutect2, varscan2
- APAF1 | c.1010G>A p.R337H (on ENST00000551964 / NM_181861.2; = p.R326H on NM_001160.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1006261171, COSV59661826; called by muse, mutect2, varscan2
- APAF1 | c.1975G>T p.E659* (on ENST00000551964 / NM_181861.2; = p.E648* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV59665541; called by muse, mutect2, varscan2
- APBA2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs763554780; called by mutect2, varscan2
- APBB1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs184224900, COSV54975089; called by muse, mutect2, varscan2
- APC | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV57342850, COSV57378951; called by muse, mutect2, varscan2
- APC | c.2843C>A p.S948Y | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV57342856; called by muse, mutect2, varscan2
- APC | c.4199C>A p.S1400* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as CM995167, COSV57324455, COSV57326621, COSV57333132; called by muse, mutect2, varscan2
- APC | c.6077C>A p.S2026Y | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57342873; called by muse, mutect2, varscan2
- APCDD1L | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV64486305; called by muse, mutect2, varscan2
- APEX2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs749036434, COSV66623956; called by mutect2, varscan2
- APLF | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769480335, COSV100377003, COSV58143504; called by muse, mutect2, varscan2
- APLNR | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs753846480, COSV57241710; called by mutect2, varscan2
- APOA4 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV63360415; called by muse, mutect2, varscan2
- APOB | c.12589C>A p.L4197M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV51934445; called by muse, mutect2, varscan2
- APOB | c.12260A>T p.K4087M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51934460; called by muse, mutect2, varscan2
- APOB | c.9445G>T p.D3149Y | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV51934474, COSV51935706; called by muse, mutect2, varscan2
- APOB | c.7759G>C p.V2587L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs375855688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.5867C>A p.S1956Y | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV51934494; called by muse, mutect2, varscan2
- APOB | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs764776276, COSV51934518; called by muse, mutect2, varscan2
- APOBEC4 | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as COSV58017601; called by mutect2, varscan2
- APOL3 | c.228G>T p.K76N (on ENST00000349314 / NM_145640.2; = p.K5N on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV62579701; called by muse, varscan2
- APP | c.1868C>A p.S623Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV60998162, COSV60998764; called by muse, mutect2, varscan2
- AQP10 | c.313T>G p.L105V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as COSV61474955; called by muse, varscan2
- AQP10 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV61474962; called by muse, varscan2
- AQP7 | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.086); catalogued as COSV53015159; called by muse, mutect2, varscan2
- AQP9 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV54967982; called by muse, mutect2, varscan2
- ARAF | c.259A>C p.I87L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV51692583; called by muse, mutect2, varscan2
- ARAP2 | c.1283A>C p.K428T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV58286278; called by muse, mutect2, varscan2
- ARF3 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV56741033, COSV56741227; called by muse, mutect2, varscan2
- ARFGEF1 | c.5458C>T p.R1820C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51584143; called by muse, mutect2, varscan2
- ARFGEF1 | c.4894G>A p.D1632N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs773060622, COSV51602227; called by muse, mutect2, varscan2
- ARFGEF1 | c.4099G>A p.D1367N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs775735472, COSV51607927; called by muse, mutect2, varscan2
- ARFGEF1 | c.3134A>G p.H1045R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.397); catalogued as COSV51607966; called by muse, mutect2, varscan2
- ARFGEF1 | c.1765A>C p.I589L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV51607984; called by muse, mutect2, varscan2
- ARFGEF2 | c.4227T>G p.I1409M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV64212143; called by muse, mutect2, varscan2
- ARFGEF2 | c.4493C>A p.S1498* | Nonsense Mutation (SNP) | VAF 35/207 reads (17%) | catalogued as COSV64212146; called by muse, mutect2, varscan2
- ARGLU1 | c.734A>C p.Q245P | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV65608377; called by muse, mutect2, varscan2
- ARHGAP10 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV60595214; called by muse, mutect2, varscan2
- ARHGAP10 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.836); catalogued as COSV60598492, COSV60598845; called by muse, mutect2, varscan2
- ARHGAP10 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs759498019, COSV60602830; called by muse, varscan2
- ARHGAP11A | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100853341, COSV64381471; called by muse, mutect2, varscan2
- ARHGAP11A | c.890T>G p.F297C | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV64380925; called by muse, mutect2, varscan2
- ARHGAP15 | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV54494546, COSV54497758; called by muse, mutect2, varscan2
- ARHGAP18 | c.1558A>C p.K520Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63764390; called by muse, mutect2, varscan2
- ARHGAP21 | c.5646A>C p.E1882D | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as COSV57605567; called by muse, mutect2, varscan2
- ARHGAP21 | c.2196A>C p.K732N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as COSV57605577; called by muse, mutect2
- ARHGAP24 | c.1286G>A p.G429D (on ENST00000395184 / NM_001025616.3; = p.G336D on NM_031305.3) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51988741; called by muse, mutect2, varscan2
- ARHGAP26 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50829120; called by muse, mutect2, varscan2
- ARHGAP28 | c.2032C>A p.H678N (on ENST00000383472 / NM_001366230.1; = p.H519N on NM_001010000.3) | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58644718, COSV58652115; called by muse, mutect2
- ARHGAP30 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV63516319; called by muse, mutect2, varscan2
- ARHGAP31 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51798776; called by mutect2, varscan2
- ARHGAP32 | c.3757G>A p.E1253K (on ENST00000310343 / NM_001378025.1; = p.E904K on NM_014715.4) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.174); catalogued as rs768865360, COSV59847417; called by muse, mutect2, varscan2
- ARHGAP35 | c.2169A>C p.Q723H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV68331094; called by muse, mutect2, varscan2
- ARHGAP35 | c.2854C>A p.H952N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV101350819; called by muse, mutect2, varscan2
- ARHGAP44 | c.2457A>C p.*819Cext*50 | Nonstop Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV52392845; called by mutect2, varscan2
- ARHGEF10 | c.2602G>A p.D868N (on ENST00000398564; = p.D843N on NM_014629.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV50648888; called by muse, mutect2, varscan2
- ARHGEF26 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV62846259; called by muse, mutect2, varscan2
- ARHGEF33 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as COSV67256897; called by muse, mutect2, varscan2
- ARHGEF33 | c.2481G>T p.K827N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67256922; called by muse, mutect2, varscan2
- ARHGEF6 | c.108A>C p.K36N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV51690326; called by muse, mutect2, varscan2
- ARHGEF9 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53637895; called by muse, mutect2, varscan2
- ARID2 | c.587A>C p.D196A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.837); catalogued as COSV57603085; called by muse, mutect2, varscan2
- ARID2 | c.4017G>T p.Q1339H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV100535614, COSV57603097; called by muse, varscan2
- ARID2 | c.4241G>T p.R1414I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as rs146518146, COSV57602936, COSV57612118; called by muse, mutect2, varscan2
- ARID3C | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as rs761685541; called by muse, mutect2, varscan2
- ARID4A | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62163569; called by muse, mutect2, varscan2
- ARID4A | c.2427T>G p.I809M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV62163580; called by muse, mutect2, varscan2
- ARID4A | c.2786G>T p.R929I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV62163591; called by muse, mutect2, varscan2
- ARID5B | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV54418922, COSV99690376; called by muse, varscan2
- ARID5B | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as rs369904878; called by mutect2, varscan2
- ARIH2 | c.828G>C p.W276C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62704683; called by muse, mutect2, varscan2
- ARL13A | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV65880115; called by muse, mutect2, varscan2
- ARL14EP | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); catalogued as COSV56342735; called by muse, varscan2
- ARL4A | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63319268; called by muse, mutect2, varscan2
- ARMC2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 36/89 reads (40%) | catalogued as COSV52900365; called by muse, mutect2, varscan2
- ARMC2 | c.1291A>C p.N431H | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV64551153; called by muse, mutect2, varscan2
- ARMC3 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473023972, COSV53059669; called by muse, mutect2, varscan2
- ARMC4 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs769348690; called by mutect2, varscan2
- ARMC6 | c.943G>A p.D315N (on ENST00000392336; = p.D290N on NM_033415.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs370794754; called by mutect2, varscan2
- ARMC8 | c.1255C>T p.R419* (on ENST00000469044 / NM_001363941.2; = p.R405* on NM_015396.6) | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV58617595, COSV58619877; called by muse, mutect2, varscan2
- ARMCX2 | c.1295T>G p.I432S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57529955; called by muse, mutect2, varscan2
- ARMCX3 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 15/21 reads (71%) | catalogued as COSV57870373; called by muse, mutect2, varscan2
- ARMH1 | c.537T>G p.N179K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62637361; called by muse, mutect2, varscan2
- ARMH4 | c.2263G>T p.E755* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV50761784, COSV50768702; called by muse, mutect2, varscan2
- ARNTL2 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV53825603; called by muse, mutect2, varscan2
- ARPP21 | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV99493118; called by mutect2, varscan2
- ARRB1 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV63575389; called by muse, mutect2, varscan2
- ARRDC3 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99475229, COSV99475257; called by muse, mutect2, varscan2
- ARSF | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV63839651; called by muse, mutect2, varscan2
- ARSL | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV66965216; called by muse, mutect2, varscan2
- ART4 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV57451851; called by muse, mutect2, varscan2
- ASAH1 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.347); catalogued as COSV50501972, COSV50504395; called by muse, mutect2, varscan2
- ASAH2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs766598373, COSV61482783; called by muse, mutect2, varscan2
- ASAP1 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1033239417; called by muse, mutect2, varscan2
- ASAP1 | c.1745T>G p.V582G | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV63048252; called by muse, mutect2, varscan2
- ASAP2 | c.798G>T p.L266F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55631382; called by muse, mutect2, varscan2
- ASAP2 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs577456546; called by mutect2, varscan2
- ASAP2 | c.2702C>A p.P901Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV55631392; called by muse, mutect2, varscan2
- ASB12 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.211); catalogued as COSV62856872; called by muse, mutect2, varscan2
- ASB2 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.687); catalogued as COSV60111684; called by muse, mutect2, varscan2
- ASB4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs138454369; called by mutect2, varscan2
- ASB5 | c.751T>G p.L251V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV56670459; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASH2L | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1246629078, COSV51698994; called by muse, mutect2, varscan2
- ASIC4 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.979); catalogued as rs750592625, COSV61731742; called by muse, mutect2, varscan2
- ASIC5 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 40/109 reads (37%) | catalogued as rs1168515854, COSV73332699; called by muse, mutect2, varscan2
- ASNSD1 | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV53623646; called by muse, varscan2
- ASNSD1 | c.1130A>C p.K377T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV53623658; called by muse, varscan2
- ASNSD1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775560677, COSV53622874; called by muse, mutect2, varscan2
- ASPSCR1 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60728613; called by muse, mutect2, varscan2
- ASPSCR1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757210501, COSV60731519; called by muse, mutect2, varscan2
- ASTE1 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200808262, COSV53907523, COSV53908737; called by muse, mutect2, varscan2
- ASTN1 | c.3487C>A p.L1163I | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62494524, COSV62496511; called by muse, mutect2, varscan2
- ASTN1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs377210940, COSV56061502; called by muse, varscan2
- ASTN2 | c.3358G>T p.E1120* (on ENST00000313400 / NM_001365069.1; = p.E1069* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV56003105; called by muse, varscan2
- ASXL3 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs753959478, COSV52465149; called by muse, mutect2, varscan2
- ASXL3 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52465157; called by muse, mutect2, varscan2
- ASXL3 | c.1059C>A p.F353L | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52463579; called by muse, varscan2
- ASZ1 | c.106-1G>T p.X36_splice | Splice Site (SNP) | VAF 8/65 reads (12%) | catalogued as COSV52912718; called by muse, mutect2, varscan2
- ATAD2 | c.3014G>A p.R1005Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs768509548, COSV54880586; called by mutect2, varscan2
- ATAD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54879779; called by muse, mutect2
- ATAD3A | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV59232944; called by muse, mutect2, varscan2
- ATF3 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV58377747; called by muse, mutect2, varscan2
- ATF6 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); catalogued as COSV63407369; called by muse, mutect2, varscan2
- ATF7 | c.1129G>T p.E377* (on ENST00000548446 / NM_001366555.2; = p.E366* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV60644208, COSV60645030; called by muse, mutect2, varscan2
- ATF7IP | c.1819T>G p.L607V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); catalogued as COSV53770409; called by muse, mutect2, varscan2
- ATF7IP2 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as COSV61093376; called by muse, varscan2
- ATF7IP2 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61093403; called by muse, mutect2, varscan2
- ATG10 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 46/125 reads (37%) | catalogued as rs1037009539, COSV56425698; called by muse, mutect2, varscan2
- ATG2B | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV63423061; called by muse, mutect2, varscan2
- ATG7 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as rs1203239812, COSV61612337; called by muse, mutect2, varscan2
- ATM | c.4222C>A p.L1408I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53727629, COSV53733404; called by muse, mutect2, varscan2
- ATP10B | c.4358G>A p.R1453H | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as rs1263758447, COSV59150868; called by muse, mutect2, varscan2
- ATP11B | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60028367; called by muse, mutect2, varscan2
- ATP11C | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59558906, COSV59560563; called by muse, mutect2, varscan2
- ATP11C | c.140G>T p.R47I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59563459; called by muse, mutect2, varscan2
- ATP13A2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs774585729, CM098010, COSV58700382; called by muse, mutect2, varscan2
- ATP1A4 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63627425; called by mutect2, varscan2
- ATP1B3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.499); catalogued as COSV53949707; called by muse, mutect2, varscan2
- ATP1B4 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54312638; called by muse, mutect2, varscan2
- ATP2B3 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as COSV54846469; called by muse, mutect2, varscan2
- ATP2B3 | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1467233293, COSV54846534; called by muse, mutect2, varscan2
- ATP2B4 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs141117629; called by muse, mutect2, varscan2
- ATP2B4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as rs376933890; called by muse, varscan2
- ATP2B4 | c.3548C>T p.A1183V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs764631446, COSV58177591; called by muse, mutect2, varscan2
- ATP6AP2 | c.1040G>A p.R347Q (on ENST00000378438; = p.R348Q on NM_005765.3) | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV65797616; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255472515, COSV57749135; called by muse, mutect2, varscan2
- ATP6V0A4 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV59475395; called by muse, mutect2, varscan2
- ATP6V0D1 | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs765114517, COSV52097924, COSV99341104; called by muse, mutect2, varscan2
- ATP6V0D2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs201622171; called by muse, mutect2, varscan2
- ATP6V1B1 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52270593; called by muse, varscan2
- ATP6V1C1 | c.734A>C p.K245T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67777962; called by muse, varscan2
- ATP6V1G1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV65013989; called by muse, mutect2, varscan2
- ATP7B | c.3562C>T p.L1188F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1432190775; called by muse, mutect2, varscan2
- ATP8A1 | c.416G>T p.R139I | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52534569; called by muse, mutect2, varscan2
- ATP8A2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1349352729, COSV54945493; called by muse, varscan2
- ATP8A2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200573494, COSV54938064; called by muse, mutect2, varscan2
- ATP8B1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as rs372749108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B2 | c.443C>A p.S148Y (on ENST00000672630; = p.S115Y on NM_001005855.2) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV100528232, COSV59245976; called by muse, mutect2, varscan2
- ATP8B2 | c.2570C>T p.T857M (on ENST00000672630; = p.T824M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs777449123, COSV59244861; called by muse, varscan2
- ATP9B | c.1810A>G p.T604A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV56950805; called by muse, mutect2, varscan2
- ATPSCKMT | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV54726733; called by muse, mutect2, varscan2
- ATPSCKMT | c.423T>G p.F141L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54726765; called by muse, varscan2
- ATR | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | catalogued as COSV63386308; called by muse, mutect2, varscan2
- ATR | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs368507270, COSV63385058; called by muse, mutect2, varscan2
- ATRNL1 | c.2508G>A p.W836* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV58087040; called by muse, mutect2, varscan2
- ATRNL1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs781814300, COSV100369594, COSV58087049; called by muse, mutect2, varscan2
- ATRX | c.4994G>T p.R1665I | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64876228; called by muse, mutect2, varscan2
- ATRX | c.1729A>C p.K577Q | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.991); catalogued as COSV64876231; called by muse, mutect2, varscan2
- ATXN10 | c.573A>C p.K191N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV53296322; called by muse, mutect2
- ATXN10 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV53296336; called by muse, mutect2, varscan2
- ATXN2 | c.2960C>T p.T987M (on ENST00000550104; = p.T827M on NM_002973.4) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758873477, COSV66483044; called by muse, mutect2, varscan2
- ATXN2 | c.2289A>C p.K763N (on ENST00000550104; = p.K603N on NM_002973.4) | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV66483050; called by muse, mutect2
- ATXN3L | c.451T>G p.F151V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV66075679; called by muse, mutect2, varscan2
- ATXN7L1 | c.1509G>T p.Q503H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV66300217; called by muse, mutect2, varscan2
- ATXN7L3 | c.488C>T p.S163F (on ENST00000389384 / NM_001382309.1; = p.S170F on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV60228281; called by muse, mutect2, varscan2
- AURKA | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57168423; called by muse, mutect2, varscan2
- AURKC | c.266G>A p.R89H (on ENST00000302804 / NM_001015878.2; = p.R55H on NM_003160.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57138443; called by muse, mutect2, varscan2
- AUTS2 | c.3526G>A p.D1176N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1309460944, COSV61399742; called by muse, mutect2, varscan2
- AVL9 | c.1681A>C p.N561H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59465529; called by muse, mutect2, varscan2
- AVPR1B | c.511_512insG p.I171Sfs*55 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as COSV65638060; called by pindel, varscan2
- AXDND1 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as COSV62642368; called by muse, varscan2
- B3GALNT1 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV57580166; called by muse, mutect2, varscan2
- B3GALT1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59907874; called by muse, varscan2
- B4GALNT2 | c.1454G>T p.R485I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV55925689; called by mutect2, varscan2
- B4GALT2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs755791825, COSV58842380; called by muse, varscan2
- B4GALT6 | c.795T>G p.F265L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV52703457; called by muse, mutect2, varscan2
- BAALC | c.536T>C p.V179A (on ENST00000297574 / NM_001364874.1; = p.V144A on NM_024812.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52562028; called by muse, mutect2, varscan2
- BACH1 | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54518799; called by muse, mutect2, varscan2
- BAHCC1 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs1428792256; called by muse, mutect2, varscan2
- BAIAP2L1 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.902); catalogued as rs1390139204, COSV99134246; called by muse, varscan2
- BAIAP2L1 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV50055769, COSV99134345; called by muse, mutect2, varscan2
- BANK1 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV100536576, COSV59842374; called by muse, mutect2, varscan2
- BARHL2 | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV64981237; called by muse, mutect2, varscan2
- BAZ1A | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 127/366 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV62410128; called by muse, mutect2, varscan2
- BAZ2A | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs560947120, COSV51636401; called by mutect2, varscan2
- BAZ2B | c.4665G>T p.K1555N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1309791346, COSV58600310; called by muse, mutect2, varscan2
- BBOF1 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780859463, COSV67454940; called by muse, mutect2, varscan2
- BBOF1 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV67454943, COSV67454950; called by muse, mutect2, varscan2
- BBS10 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.737); catalogued as COSV53882140; called by muse, mutect2, varscan2
- BBS10 | c.534T>G p.F178L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV53882145; called by muse, mutect2, varscan2
- BBS10 | c.383T>G p.F128C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53882153; called by muse, mutect2, varscan2
- BBS12 | c.469T>G p.L157V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV58562005; called by muse, mutect2, varscan2
- BBS12 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58562014; called by muse, mutect2, varscan2
- BBS7 | c.1424G>T p.R475I | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV52655313; called by muse, mutect2, varscan2
- BBS9 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 24/126 reads (19%) | catalogued as rs767005321, CM102570, COSV54164887, COSV54165364; called by muse, mutect2, varscan2
- BCAN | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763839731, COSV61256773; called by muse, mutect2, varscan2
- BCAT1 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV53911037; called by muse, mutect2, varscan2
- BCDIN3D | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs772541621, COSV61702417; called by muse, mutect2, varscan2
- BCHE | c.1415T>A p.F472Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV52256622; called by muse, mutect2, varscan2
- BCHE | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.204); catalogued as COSV52255254, COSV52261070; called by muse, mutect2, varscan2
- BCL2L14 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.385); catalogued as rs1196046884; called by muse, mutect2, varscan2
- BCL2L2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.076); catalogued as rs745978918, COSV51635366; called by muse, mutect2, varscan2
- BCL9 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52341693; called by muse, mutect2, varscan2
- BCOR | c.4747T>G p.L1583V (on ENST00000378444 / NM_001123385.2; = p.L1549V on NM_017745.6) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV60706593; called by muse, mutect2, varscan2
- BCORL1 | c.2787G>T p.Q929H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV54406645; called by muse, mutect2, varscan2
- BCORL1 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as CM137531, COSV54395864; called by muse, mutect2, varscan2
- BDP1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62431219, COSV62434684; called by muse, mutect2, varscan2
- BDP1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62431223; called by muse, varscan2
- BDP1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.147); catalogued as rs756417651, COSV62431133; called by muse, varscan2
- BDP1 | c.2173C>A p.L725I | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV62432140; called by muse, mutect2, varscan2
- BEND2 | c.1451G>T p.R484I | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66215644, COSV66215770; called by muse, mutect2
- BEND5 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs756507130, COSV65717230; called by mutect2, varscan2
- BEX3 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55421227, COSV55421245; called by muse, mutect2, varscan2
- BFSP1 | c.1448G>T p.R483I | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64900195; called by muse, mutect2, varscan2
- BICRAL | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs149708370, COSV58408371; called by mutect2, varscan2
- BIRC2 | c.1323A>C p.K441N | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV57161340; called by muse, varscan2
- BIRC3 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54818724; called by muse, mutect2, varscan2
- BIRC6 | c.2658G>T p.K886N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.627); catalogued as rs747004451, COSV70195739; called by muse, varscan2
- BIRC6 | c.5474A>G p.E1825G | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370894404; called by muse, mutect2, varscan2
- BIRC6 | c.9817G>A p.E3273K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70198988; called by muse, varscan2
- BIRC6 | c.12005T>A p.I4002K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV66042836; called by muse, mutect2, varscan2
- BIRC6 | c.13133G>A p.R4378Q | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs146403054; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1899C>A p.F633L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV63244998; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3817C>T p.R1273W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770975661, CM065154, COSV63243835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLM | c.3755C>A p.S1252Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100756882, COSV61923990; called by muse, mutect2, varscan2
- BLMH | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480557860, COSV55585417; called by muse, mutect2, varscan2
- BLOC1S2 | c.256A>C p.N86H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62489581; called by muse, varscan2
- BMI1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs530837837, COSV64959026; called by muse, mutect2, varscan2
- BMP15 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs367885992, COSV53140423; called by muse, mutect2, varscan2
- BMP3 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51083695; called by muse, mutect2, varscan2
- BMP5 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100896302; called by mutect2, varscan2
- BMPR1A | c.67+2T>C p.X23_splice | Splice Site (SNP) | VAF 29/99 reads (29%) | catalogued as COSV64405957; called by muse, mutect2, varscan2
- BOD1L1 | c.6457G>A p.E2153K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs773336847, COSV50012307; called by mutect2, varscan2
- BOD1L1 | c.4321G>T p.D1441Y | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV50012351; called by muse, mutect2, varscan2
- BORCS7 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs1215818434, COSV54916822; called by muse, mutect2, varscan2
- BPI | c.931C>A p.L311I (on ENST00000262865; = p.L307I on NM_001725.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV53405542; called by muse, mutect2, varscan2
- BPIFB3 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV64957303; called by muse, varscan2
- BPIFC | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs78469100, COSV55910676; called by muse, mutect2, varscan2
- BPTF | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV58836775; called by muse, mutect2, varscan2
- BPTF | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs941388732, COSV58836793, COSV58838635; called by muse, mutect2, varscan2
- BPTF | c.4024G>A p.D1342N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs760275783, COSV58836810; called by muse, mutect2, varscan2
- BRAF | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs397507472, COSV56068050; ClinVar: uncertain significance; called by muse, varscan2
- BRAF | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.248); catalogued as COSV56101984; called by muse, mutect2, varscan2
- BRCA2 | c.2164A>C p.K722Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV66453349; called by muse, mutect2, varscan2
- BRCA2 | c.3141T>G p.I1047M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV66453355; called by muse, mutect2, varscan2
- BRCA2 | c.4790C>A p.S1597Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.067); catalogued as rs876660146, COSV66451830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.7132T>G p.S2378A | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as COSV66453369; called by muse, mutect2, varscan2
- BRCA2 | c.7481G>A p.R2494Q | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs80358973, COSV66449976; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.9539T>G p.L3180R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs397507431, COSV66337295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57702323; called by muse, mutect2, varscan2
- BRD8 | c.3641G>T p.R1214I | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV54522732; called by muse, mutect2, varscan2
- BRD8 | c.3539T>G p.V1180G | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54522739; called by muse, mutect2, varscan2
- BRD8 | c.3022G>A p.V1008I | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV54726451; called by muse, mutect2, varscan2
- BRDT | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs765131878, COSV61771156; called by muse, mutect2, varscan2
- BRDT | c.738A>C p.K246N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV62864862; called by muse, mutect2
- BRINP1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV56299353; called by muse, mutect2, varscan2
- BRINP3 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66523372; called by muse, mutect2, varscan2
- BRIX1 | c.62G>T p.R21I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1179317560, COSV57715167; called by muse, mutect2, varscan2
- BRIX1 | c.707T>G p.F236C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57760545; called by muse, mutect2, varscan2
- BRSK1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1271951177, COSV58665422; called by muse, mutect2, varscan2
- BRSK2 | c.1575C>A p.F525L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV100373108; called by muse, mutect2, varscan2
- BRWD1 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as rs750289132, COSV60892937; called by muse, varscan2
- BRWD3 | c.4170T>G p.F1390L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV64747662; called by muse, mutect2, varscan2
- BSN | c.516A>G p.I172M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56517405; called by muse, mutect2, varscan2
- BSN | c.4855C>T p.P1619S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1251089604, COSV56517421; called by muse, mutect2, varscan2
- BSN | c.9049C>T p.L3017F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56517433; called by muse, varscan2
- BSND | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347253611; called by muse, mutect2, varscan2
- BTAF1 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.798); catalogued as COSV56433674; called by muse, mutect2, varscan2
- BTAF1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs754526608, COSV56433682; called by mutect2, varscan2
- BTAF1 | c.3196T>G p.F1066V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56433702; called by muse, mutect2, varscan2
- BTBD11 | c.3181G>A p.E1061K (on ENST00000280758 / NM_001018072.2; = p.E598K on NM_001017523.2) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs897076308, COSV55023919; called by muse, mutect2, varscan2
- BTBD8 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV61546205; called by muse, mutect2, varscan2
- BTBD8 | c.3251T>G p.F1084C (on ENST00000636805 / NM_001376131.1; = p.F571C on NM_015237.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV64884133; called by muse, mutect2, varscan2
- BTBD8 | c.4579A>G p.K1527E (on ENST00000636805 / NM_001376131.1; = p.K1014E on NM_015237.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs1367920215, COSV64884366; called by muse, mutect2, varscan2
- BTG4 | c.667T>G p.L223V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100604588, COSV63635695; called by muse, varscan2
- BTLA | c.355T>G p.F119V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.101); catalogued as COSV57938359; called by muse, varscan2
- BTN2A2 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV61857310; called by muse, mutect2, varscan2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, mutect2, varscan2
- BUB1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs975621280, COSV57063381; called by muse, mutect2, varscan2
- BUB1 | c.224T>G p.F75C | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV57063401; called by muse, mutect2, varscan2
- BUB1B | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1372115983, COSV55012371, COSV99807233; called by muse, mutect2, varscan2
- BVES | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58947559; called by muse, varscan2
- BYSL | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs753749685, COSV57828467; called by muse, mutect2, varscan2
- BZW1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV63349698; called by muse, mutect2, varscan2
- C10orf105 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.074); catalogued as rs371701194, COSV56462245; called by muse, mutect2, varscan2
- C10orf120 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as rs1480468524, COSV61491914; called by muse, mutect2
- C10orf71 | c.2825C>T p.S942L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs1432480938, COSV60507420; called by muse, mutect2, varscan2
- C10orf90 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs765177499, COSV52949317, COSV99505179; called by mutect2, varscan2
- C11orf1 | c.184A>C p.N62H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52788440; called by muse, mutect2, varscan2
- C11orf52 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV53714599; called by muse, mutect2
- C12orf4 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1301114797; called by muse, mutect2, varscan2
- C12orf4 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54206879, COSV54208273; called by muse, varscan2
- C12orf40 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV61132247; called by muse, varscan2
- C12orf40 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV61132265; called by muse, mutect2, varscan2
- C12orf56 | c.1233A>C p.E411D (on ENST00000543942 / NM_001170633.2; = p.E251D on NM_001099676.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.668); catalogued as COSV61486883; called by muse, varscan2
- C12orf60 | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.975); catalogued as COSV57451286, COSV57451835; called by muse, mutect2, varscan2
- C12orf66 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV61323109; called by muse, mutect2, varscan2
- C12orf66 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61323115; called by muse, mutect2, varscan2
- C12orf75 | c.108-1G>A p.X36_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV71664355; called by muse, mutect2, varscan2
- C14orf39 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs758761993, COSV58781130; called by muse, varscan2
- C14orf39 | c.1364G>T p.R455I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV58781496, COSV58781699; called by muse, varscan2
- C14orf39 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 49/189 reads (26%) | catalogued as COSV58781711; called by muse, varscan2
- C14orf39 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs758496044, COSV58779694; called by muse, mutect2, varscan2
- C16orf46 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV55151050; called by muse, mutect2, varscan2
- C16orf46 | c.140T>G p.V47G | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV100215456; called by muse, mutect2, varscan2
- C16orf71 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs746265671, COSV54788064; called by muse, mutect2, varscan2
- C16orf87 | c.339A>C p.E113D | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53511891; called by muse, mutect2, varscan2
- C17orf64 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as rs1456917549, COSV52256415, COSV52256516; called by muse, mutect2, varscan2
- C18orf21 | c.626A>C p.N209T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.344); catalogued as COSV52449399; called by muse, mutect2, varscan2
- C19orf44 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs750835848, COSV55612071; called by muse, mutect2, varscan2
- C1GALT1C1L | c.708T>G p.D236E | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs756180281; called by muse, varscan2
- C1QTNF3 | c.657G>C p.W219C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV51468537; called by muse, mutect2, varscan2
- C1QTNF3 | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51468554; called by muse, mutect2, varscan2
- C1orf100 | c.422G>T p.R141I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1558260625, COSV57372712; called by muse, varscan2
- C1orf185 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100874458; called by muse, mutect2, varscan2
- C20orf194 | c.2213C>T p.T738I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV52695569; called by muse, mutect2, varscan2
9,967 further variants in this file (7,329 protein-altering or splice-affecting, 1,623 silent, 1,015 other) are not listed here.
